Somatic mutation profile of tumor specimen TARGET-40-PAKUZU-01A (aliquot TARGET-40-PAKUZU-01A-01D) from TARGET case TARGET-40-PAKUZU, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 19.9 years (7,270 days).
Specimen TARGET-40-PAKUZU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 054cc81a-2abc-494b-8653-25a6ce77d599.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAKUZU-10A (Blood Derived Normal), aliquot TARGET-40-PAKUZU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b49dfaf-f338-4546-82b2-292b6ac51999

The open-access MAF lists 33 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Intron 1, Frame Shift Del 1, 3'UTR 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM29 | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV63668153; called by muse, mutect2
- ATCAY | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750960090; called by muse, mutect2, varscan2
- KCNT2 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); catalogued as rs1202140933, COSV99652906; called by muse, mutect2
- OR10H3 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100008485; called by muse, mutect2, varscan2
- PCDH15 | c.3172A>G p.I1058V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.196); catalogued as COSV100225564; called by muse, mutect2, varscan2
- PGR | c.2768G>A p.G923E | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565326353; called by muse, mutect2, varscan2
- RB1 | c.2247T>G p.Y749* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as CM143230, COSV57300323; called by muse, varscan2
- WIZ | c.3877C>A p.R1293S (on ENST00000673675 / NM_001371589.1; = p.R198S on NM_021241.3) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54607259; called by muse, mutect2, varscan2
- XIRP1 | c.3932C>G p.T1311S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.08); catalogued as COSV61139622; called by muse, mutect2, varscan2
- AGAP6 | c.698C>A p.S233Y (on ENST00000374056 / NM_001365867.1; = p.S256Y on NM_001077665.2) | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- COL4A2 | c.5102A>G p.H1701R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- EIPR1 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCGBP | c.8078G>T p.C2693F | Missense Mutation (SNP) | VAF 18/508 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HECTD4 | c.2870T>C p.L957S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ITIH2 | c.1322A>T p.N441I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- MAP2 | c.4819C>A p.P1607T | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PACSIN1 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PIK3C2G | c.638A>C p.Q213P | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPIL6 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PUS7 | c.1078_1087del p.Q360* | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- SIDT1 | c.270C>G p.N90K | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF667 | c.828T>A p.N276K | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- HECTD3 | c.2119C>A p.R707= | Silent (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- IQSEC3 | c.1461C>T p.D487= (on ENST00000538872 / NM_001170738.2; = p.D184= on NM_015232.1) | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV58284098; called by muse, mutect2
- NRXN1 | c.867T>C p.S289= | Silent (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2
- PLPPR4 | c.2112C>T p.R704= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1444574680, COSV64564436; called by muse, mutect2, varscan2
- PRKACG | c.480G>A p.S160= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- RBP5 | c.378G>A p.V126= | Silent (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- SPEM2 | c.1308G>A p.A436= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs770047620; called by muse, mutect2, varscan2
- UNCX | c.420G>A p.L140= | Silent (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- BSPRY | c.*84G>A | 3'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.2237G>A | RNA (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- TNXB | c.403+24G>T | Intron (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
